Somatic mutation profile of tumor specimen MBCProject_2741_T1_WES (aliquot MBCProject_2741_T1_WES_1) from CMI case MBCProject_2741, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 63.7 years (23,284 days).
Specimen MBCProject_2741_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6133a3c6-f276-419d-b0db-01ac0fd5a302.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_2741_SALIVA (Saliva), aliquot MBCProject_2741_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/784cde94-1369-453a-a304-1a643518bbe6

The open-access MAF lists 159 somatic variants for this specimen: 95 protein-altering or splice-affecting, 43 silent, 21 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 80, Silent 43, Intron 8, Frame Shift Del 4, Nonsense Mutation 4, 5'UTR 4, 3'UTR 3, Splice Region 3, In Frame Del 2, Splice Site 2, RNA 2, 5'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.584T>C p.I195T | Missense Mutation (SNP) | VAF 121/210 reads (58%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs760043106, CM092575, COSV52661172, COSV52664264, COSV52684176, COSV52720899; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACTN2 | c.1324C>T p.R442W | Missense Mutation (SNP) | VAF 48/375 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs769073315, COSV63978665; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADAMTS2 | c.758C>T p.S253L | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.06); catalogued as rs750197805, COSV51072125; called by muse, mutect2, varscan2
- ADGRV1 | c.6635G>C p.G2212A | Missense Mutation (SNP) | VAF 34/153 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV67982301; called by muse, mutect2, varscan2
- ARID1A | c.2078G>A p.R693Q | Missense Mutation (SNP) | VAF 20/306 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.978); catalogued as rs770764901, COSV100251173, COSV61377517; called by muse, mutect2
- ATP1A2 | c.1139C>A p.T380N | Missense Mutation (SNP) | VAF 222/545 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63403627; called by muse, mutect2, varscan2
- B4GALNT3 | c.2758G>C p.E920Q | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.326); catalogued as COSV99078769; called by muse, mutect2, varscan2
- CACNA1H | c.2548C>G p.L850V | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.339); catalogued as rs1317099790; called by muse, mutect2
- CACNA1H | c.3808G>A p.E1270K | Missense Mutation (SNP) | VAF 29/136 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.061); catalogued as rs545971270, COSV61993545; called by muse, mutect2, varscan2
- CCDC82 | c.1362C>G p.F454L | Missense Mutation (SNP) | VAF 35/266 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.626); catalogued as COSV53592125; called by muse, mutect2, varscan2
- CEP112 | c.2104C>T p.R702C | Missense Mutation (SNP) | VAF 20/259 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); catalogued as rs780421901, COSV67142461; called by muse, mutect2
- CFAP61 | c.3605G>C p.R1202T | Missense Mutation (SNP) | VAF 56/592 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.447); catalogued as COSV55622884; called by muse, mutect2
- CMYA5 | c.6307G>A p.E2103K | Missense Mutation (SNP) | VAF 26/121 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.371); catalogued as rs560368604, COSV71404525; called by muse, mutect2, varscan2
- CRYBG1 | c.2716G>A p.E906K | Missense Mutation (SNP) | VAF 40/340 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.757); catalogued as COSV64811517; called by muse, mutect2, varscan2
- DBN1 | c.1750G>A p.E584K | Missense Mutation (SNP) | VAF 23/215 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV52788476; called by muse, mutect2, varscan2
- DISP1 | c.11G>C p.S4T | Missense Mutation (SNP) | VAF 17/228 reads (7%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.115); catalogued as COSV99450203; called by muse, mutect2
- DMD | c.2963C>G p.S988C | Missense Mutation (SNP) | VAF 11/166 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.927); catalogued as COSV63742571; called by muse, mutect2
- DROSHA | c.3505C>T p.H1169Y | Missense Mutation (SNP) | VAF 36/151 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as COSV60772758; called by muse, mutect2, varscan2
- DST | c.15657G>C p.K5219N (on ENST00000361203 / NM_001374722.1; = p.K2807N on NM_015548.5) | Missense Mutation (SNP) | VAF 74/487 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.171); catalogued as COSV55013011; called by muse, mutect2, varscan2
- FMN2 | c.1407C>G p.H469Q | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.79); PolyPhen benign (0.006); catalogued as COSV60447306; called by muse, varscan2
- GABRB3 | c.880C>T p.R294W | Missense Mutation (SNP) | VAF 40/351 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs769077258, COSV54660540; called by muse, mutect2, varscan2
- GINS4 | c.368C>T p.S123L | Missense Mutation (SNP) | VAF 8/121 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52531271; called by muse, mutect2
- HMBOX1 | c.155G>A p.R52H | Missense Mutation (SNP) | VAF 97/563 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as rs777042809, COSV55065757; called by muse, mutect2, varscan2
- HTR5A | c.429C>G p.I143M | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV99839556; called by muse, mutect2, varscan2
- ITGA4 | c.2128G>C p.D710H | Missense Mutation (SNP) | VAF 30/289 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.944); catalogued as rs764498817; called by muse, mutect2
- KIAA1614 | c.3032C>T p.S1011L | Missense Mutation (SNP) | VAF 17/184 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.027); catalogued as COSV62550626; called by muse, mutect2, varscan2
- KRT73 | c.470A>G p.N157S | Missense Mutation (SNP) | VAF 20/140 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760029002; called by muse, mutect2, varscan2
- MYH8 | c.271G>C p.E91Q | Missense Mutation (SNP) | VAF 30/154 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as COSV67964748; called by muse, mutect2, varscan2
- MYO7B | c.616C>T p.R206C | Missense Mutation (SNP) | VAF 42/101 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs748812090, COSV67347950; called by muse, mutect2, varscan2
- MYOT | c.689G>A p.R230K | Missense Mutation (SNP) | VAF 25/224 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.421); catalogued as COSV99525025; called by muse, mutect2, varscan2
- PAX9 | c.991G>A p.E331K | Missense Mutation (SNP) | VAF 38/490 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.074); catalogued as COSV58721264; called by muse, mutect2
- PRPF18 | c.513G>A p.A171= | Splice Region (SNP) | VAF 73/452 reads (16%) | catalogued as rs368540337; called by muse, varscan2
- RAPGEF2 | c.265G>A p.D89N | Missense Mutation (SNP) | VAF 38/255 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.495); catalogued as COSV52425527, COSV52426157; called by muse, mutect2, varscan2
- RAPGEF5 | c.235C>G p.L79V | Missense Mutation (SNP) | VAF 35/257 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0.031); catalogued as rs918756941; called by muse, varscan2
- RELN | c.1901G>A p.R634Q | Missense Mutation (SNP) | VAF 46/387 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as rs779205093, COSV58986231; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SORBS1 | c.683C>T p.S228F (on ENST00000361941 / NM_001034954.2; = p.S196F on NM_015385.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.306); catalogued as rs898872895, COSV99527488; called by muse, mutect2
- TBC1D10C | c.1273G>A p.G425S | Missense Mutation (SNP) | VAF 51/90 reads (57%) | SIFT deleterious (0.05); PolyPhen benign (0.156); catalogued as COSV56705885; called by muse, mutect2, varscan2
- TFEB | c.505G>A p.D169N | Missense Mutation (SNP) | VAF 25/118 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs1311125282, COSV100026507; called by muse, mutect2, varscan2
- TRA2B | c.856C>A p.R286S | Missense Mutation (SNP) | VAF 16/146 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.726); catalogued as COSV52025939; called by muse, mutect2, varscan2
- VPS8 | c.2206C>T p.R736C (on ENST00000625842 / NM_001349294.1; = p.R734C on NM_015303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/330 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs781736257, COSV54998419; called by muse, mutect2, varscan2
- WDR44 | c.2300G>A p.R767K | Missense Mutation (SNP) | VAF 33/144 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV54166810; called by muse, mutect2
- ZNF275 | c.1171G>A p.G391S | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT tolerated (0.76); PolyPhen benign (0.259); catalogued as rs782626018, COSV64705253; called by muse, mutect2, varscan2
- ZNF768 | c.775C>T p.R259W | Missense Mutation (SNP) | VAF 10/190 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.948); catalogued as rs1176774306, COSV63320979; called by muse, mutect2
- ZNF99 | c.2069C>A p.S690* | Nonsense Mutation (SNP) | VAF 19/147 reads (13%) | catalogued as COSV101233841, COSV68054546; called by muse, varscan2
- ATRX | c.2750C>A p.S917Y | Missense Mutation (SNP) | VAF 16/252 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.073); called by muse, mutect2
- AVIL | c.1262_1276del p.G421_L425del | In Frame Del (DEL) | VAF 37/277 reads (13%) | called by mutect2, pindel, varscan2
- BRAT1 | c.1672G>T p.E558* | Nonsense Mutation (SNP) | VAF 12/77 reads (16%) | called by muse, mutect2, varscan2
- CACNA1G | c.7096T>C p.S2366P | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CCDC120 | c.1211C>A p.T404N | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.54); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CDHR4 | c.344C>T p.S115F | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDS2 | c.588+1G>A p.X196_splice | Splice Site (SNP) | VAF 101/248 reads (41%) | called by muse, mutect2, varscan2
- CLPSL1 | c.39_43del p.F14Lfs*66 | Frame Shift Del (DEL) | VAF 80/198 reads (40%) | called by pindel, varscan2
- CSMD1 | c.6404A>T p.N2135I (on ENST00000520002; = p.N2134I on NM_033225.6) | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DLEC1 | c.2155G>A p.V719I | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DOCK7 | c.5651G>C p.R1884T (on ENST00000635253 / NM_001367561.1; = p.R1853T on NM_033407.3) | Missense Mutation (SNP) | VAF 8/189 reads (4%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.821); called by muse, mutect2
- EIF4EBP1 | c.16A>C p.S6R | Missense Mutation (SNP) | VAF 16/135 reads (12%) | SIFT tolerated (0.52); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ERBB3 | c.733-5C>A | Splice Region (SNP) | VAF 30/453 reads (7%) | called by muse, mutect2
- ERBB3 | c.1613+6G>T | Splice Region (SNP) | VAF 7/120 reads (6%) | called by muse, mutect2
- ERICH6B | c.2023G>A p.E675K | Missense Mutation (SNP) | VAF 35/165 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- ETS1 | c.85A>T p.N29Y | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- F9 | c.725T>G p.V242G | Missense Mutation (SNP) | VAF 24/268 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- FBXO42 | c.917A>G p.N306S | Missense Mutation (SNP) | VAF 56/190 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- FYB2 | c.1168C>A p.P390T | Missense Mutation (SNP) | VAF 47/246 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- GALNT14 | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 23/179 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- GPS2 | c.562_568del p.Y188Lfs*155 | Frame Shift Del (DEL) | VAF 32/79 reads (41%) | called by mutect2, pindel, varscan2
- GTF3C2 | c.428G>A p.R143Q | Missense Mutation (SNP) | VAF 36/344 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2
- H1-3 | c.593C>T p.P198L | Missense Mutation (SNP) | VAF 56/467 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- HTR3A | c.867C>G p.I289M | Missense Mutation (SNP) | VAF 13/150 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); called by muse, mutect2
- LGSN | c.1393G>T p.A465S | Missense Mutation (SNP) | VAF 31/218 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- LRP12 | c.1862T>C p.V621A | Missense Mutation (SNP) | VAF 44/354 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- MAGEA1 | c.104C>T p.S35F | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NDST1 | c.805G>A p.D269N | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NIT1 | c.592-1G>C p.X198_splice | Splice Site (SNP) | VAF 16/206 reads (8%) | called by muse, mutect2
- NRG2 | c.1475C>T p.T492I | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- PAX7 | c.471_495del p.S157Rfs*49 | Frame Shift Del (DEL) | VAF 23/93 reads (25%) | called by mutect2, pindel
- PHACTR4 | c.287G>C p.G96A (on ENST00000373839 / NM_001350159.2; = p.G106A on NM_023923.4) | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT tolerated (0.6); PolyPhen benign (0.294); called by muse, mutect2
- PMPCA | c.1046C>T p.S349F | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PPP6R3 | c.199C>T p.Q67* | Nonsense Mutation (SNP) | VAF 19/157 reads (12%) | called by muse, varscan2
- RAD54B | c.2414C>T p.S805L | Missense Mutation (SNP) | VAF 29/201 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- RANBP3 | c.1168G>A p.E390K (on ENST00000340578 / NM_007322.3; = p.E385K on NM_003624.3) | Missense Mutation (SNP) | VAF 38/162 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- RAPGEF3 | c.223C>T p.P75S (on ENST00000389212; = p.P33S on NM_006105.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/285 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2
- SIGLEC6 | c.496T>G p.C166G | Missense Mutation (SNP) | VAF 21/161 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SIN3A | c.1997G>A p.R666K | Missense Mutation (SNP) | VAF 21/172 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- SLC2A5 | c.1067G>A p.C356Y | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- SPTB | c.3526G>A p.D1176N | Missense Mutation (SNP) | VAF 28/241 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- TMEM247 | c.546C>G p.I182M | Missense Mutation (SNP) | VAF 26/298 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- TMEM94 | c.3271A>T p.K1091* | Nonsense Mutation (SNP) | VAF 66/101 reads (65%) | called by muse, mutect2, varscan2
- TRPM5 | c.1512G>C p.Q504H | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.605); called by muse, mutect2, varscan2
- TTC12 | c.1169T>C p.L390P | Missense Mutation (SNP) | VAF 28/222 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- TTF2 | c.1253_1264del p.T418_L421del | In Frame Del (DEL) | VAF 14/70 reads (20%) | called by mutect2, pindel
- TTN | c.7792G>A p.D2598N (on ENST00000591111; = p.D2552N on NM_003319.4) | Missense Mutation (SNP) | VAF 12/147 reads (8%) | PolyPhen benign (0.037); called by muse, mutect2
- UBR4 | c.12736_12737del p.S4246Lfs*4 | Frame Shift Del (DEL) | VAF 18/77 reads (23%) | called by pindel, varscan2
- WASHC2C | c.3277G>A p.E1093K (on ENST00000336378; = p.E1072K on NM_015262.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 79/423 reads (19%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- ZFHX3 | c.8100G>T p.Q2700H | Missense Mutation (SNP) | VAF 15/128 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ZNF669 | c.815A>G p.H272R | Missense Mutation (SNP) | VAF 12/158 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- AKAP6 | c.2790C>T p.L930= | Silent (SNP) | VAF 33/331 reads (10%) | catalogued as COSV99797986, COSV99803177; called by muse, mutect2
- BACH1 | c.66C>G p.L22= | Silent (SNP) | VAF 46/164 reads (28%) | catalogued as rs1028243602; called by muse, varscan2
- CACNA1E | c.6588C>A p.T2196= (on ENST00000367573 / NM_001205293.3; = p.T2153= on NM_000721.4) | Silent (SNP) | VAF 14/194 reads (7%) | called by muse, mutect2
- CATSPER2 | c.654C>G p.L218= | Silent (SNP) | VAF 123/233 reads (53%) | called by muse, mutect2, varscan2
- CCNQ | c.387G>C p.L129= | Silent (SNP) | VAF 14/312 reads (4%) | called by muse, mutect2
- CDC14A | c.816G>A p.G272= | Silent (SNP) | VAF 28/180 reads (16%) | called by muse, mutect2, varscan2
- CDC42EP3 | c.591C>T p.P197= | Silent (SNP) | VAF 10/118 reads (8%) | catalogued as rs756248339; called by muse, mutect2
- CSE1L | c.2904G>A p.V968= | Silent (SNP) | VAF 22/336 reads (7%) | called by muse, mutect2
- DCAF4L2 | c.213C>T p.S71= | Silent (SNP) | VAF 116/278 reads (42%) | called by muse, mutect2, varscan2
- DCLRE1A | c.1056G>A p.L352= | Silent (SNP) | VAF 25/137 reads (18%) | called by muse, mutect2, varscan2
- EHD1 | c.294C>T p.I98= | Silent (SNP) | VAF 14/76 reads (18%) | called by muse, mutect2, varscan2
- FMOD | c.801G>A p.A267= | Silent (SNP) | VAF 51/131 reads (39%) | catalogued as rs750163069, COSV61610385; called by muse, mutect2, varscan2
- GMEB2 | c.1440G>A p.L480= | Silent (SNP) | VAF 171/220 reads (78%) | called by muse, mutect2, varscan2
- HDLBP | c.3354G>A p.L1118= | Silent (SNP) | VAF 23/155 reads (15%) | called by muse, mutect2, varscan2
- HIF3A | c.1546C>T p.L516= (on ENST00000377670 / NM_152795.4; = p.L447= on NM_022462.4) | Silent (SNP) | VAF 6/72 reads (8%) | catalogued as rs1230968710; called by muse, mutect2
- HS3ST4 | c.969G>T p.L323= | Silent (SNP) | VAF 83/207 reads (40%) | catalogued as COSV100503257; called by muse, mutect2, varscan2
- IGLV7-43 | c.84A>G p.S28= | Silent (SNP) | VAF 7/60 reads (12%) | called by muse, mutect2, varscan2
- INA | c.282G>A p.E94= | Silent (SNP) | VAF 45/75 reads (60%) | called by muse, mutect2, varscan2
- KLKB1 | c.567C>T p.F189= | Silent (SNP) | VAF 16/266 reads (6%) | catalogued as rs1561454539; called by muse, mutect2
- MAGEB10 | c.576G>A p.L192= | Silent (SNP) | VAF 19/119 reads (16%) | called by muse, mutect2, varscan2
- MOV10 | c.2490C>T p.I830= | Silent (SNP) | VAF 13/112 reads (12%) | catalogued as rs1296850321, COSV53517474; called by muse, mutect2, varscan2
- MYO18A | c.1452G>A p.A484= | Silent (SNP) | VAF 35/221 reads (16%) | catalogued as rs770294431; called by muse, mutect2, varscan2
- NPHP4 | c.1980A>G p.T660= | Silent (SNP) | VAF 40/97 reads (41%) | catalogued as rs201184309; called by muse, mutect2, varscan2
- OCLN | c.1165A>C p.R389= | Silent (SNP) | VAF 109/192 reads (57%) | called by muse, mutect2, varscan2
- PCDHB5 | c.1962C>T p.T654= | Silent (SNP) | VAF 16/117 reads (14%) | catalogued as COSV50652418; called by muse, mutect2, varscan2
- PDX1 | c.747G>A p.P249= | Silent (SNP) | VAF 12/39 reads (31%) | called by muse, mutect2, varscan2
- PIEZO1 | c.3681C>T p.I1227= | Silent (SNP) | VAF 13/55 reads (24%) | called by muse, mutect2
- PODXL2 | c.1530C>T p.A510= | Silent (SNP) | VAF 46/136 reads (34%) | called by muse, mutect2, varscan2
- RBM7 | c.729T>C p.D243= | Silent (SNP) | VAF 36/138 reads (26%) | called by mutect2, varscan2
- SVOPL | c.375C>T p.A125= | Silent (SNP) | VAF 25/181 reads (14%) | catalogued as rs200761598; called by muse, mutect2, varscan2
- SYNRG | c.3894C>T p.I1298= | Silent (SNP) | VAF 96/164 reads (59%) | called by muse, mutect2, varscan2
- TBC1D12 | c.795C>T p.G265= | Silent (SNP) | VAF 22/173 reads (13%) | catalogued as rs1351797162; called by muse, mutect2, varscan2
- TCF20 | c.3066G>A p.R1022= | Silent (SNP) | VAF 113/193 reads (59%) | called by muse, mutect2, varscan2
- TDRD6 | c.1149C>T p.D383= | Silent (SNP) | VAF 25/51 reads (49%) | catalogued as rs757611177, COSV60175332; called by muse, mutect2, varscan2
- TG | c.3369C>T p.G1123= | Silent (SNP) | VAF 70/480 reads (15%) | called by muse, mutect2, varscan2
- TGM6 | c.648C>T p.Y216= | Silent (SNP) | VAF 29/514 reads (6%) | catalogued as rs140141767, COSV52482855; called by muse, mutect2
- TMEM183A | c.489C>T p.V163= | Silent (SNP) | VAF 20/369 reads (5%) | called by muse, mutect2
- TMEM200C | c.1242G>T p.P414= | Silent (SNP) | VAF 12/82 reads (15%) | catalogued as COSV67309798; called by muse, mutect2, varscan2
- UNKL | c.762C>T p.H254= | Silent (SNP) | VAF 6/100 reads (6%) | catalogued as rs958360430, COSV57019366; called by muse, mutect2
- UTRN | c.4464C>G p.V1488= | Silent (SNP) | VAF 18/121 reads (15%) | called by muse, mutect2, varscan2
- ZFPM2 | c.1569G>T p.L523= | Silent (SNP) | VAF 66/357 reads (18%) | called by muse, mutect2, varscan2
- ZNF33A | c.1680C>T p.F560= (on ENST00000458705 / NM_006974.3; = p.F561= on NM_006954.2) | Silent (SNP) | VAF 50/554 reads (9%) | called by muse, mutect2
- ZNF423 | c.2211C>T p.F737= (on ENST00000563137 / NM_001379286.1; = p.F729= on NM_015069.4) | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as rs138278000, COSV99283511; called by muse, mutect2, varscan2
- ADAM9 | c.-61G>A | 5'UTR (SNP) | VAF 33/391 reads (8%) | called by muse, mutect2
- AL353804.4 | chrX:73824207 G>A | 5'Flank (SNP) | VAF 13/361 reads (4%) | called by muse, mutect2
- AP000769.5 | chr11:65499697 del AAG | 5'Flank (DEL) | VAF 156/393 reads (40%) | catalogued as rs1240098525; called by mutect2, pindel, varscan2
- CATSPERD | c.1942-896G>T | Intron (SNP) | VAF 41/106 reads (39%) | called by muse, mutect2, varscan2
- CIB3 | c.-19C>T | 5'UTR (SNP) | VAF 29/132 reads (22%) | called by muse, mutect2, varscan2
- CTBP2 | c.59-2125C>T | Intron (SNP) | VAF 72/163 reads (44%) | called by muse, mutect2, varscan2
- CTCFL | c.1674+762G>A | Intron (SNP) | VAF 22/338 reads (7%) | called by muse, mutect2
- CYP2R1 | c.-14T>G | 5'UTR (SNP) | VAF 44/179 reads (25%) | called by muse, mutect2, varscan2
- DENND3 | c.-238C>A | 5'UTR (SNP) | VAF 30/42 reads (71%) | catalogued as rs772484656; called by muse, varscan2
- DIO3OS | chr14:101552637 G>A | 3'Flank (SNP) | VAF 14/68 reads (21%) | catalogued as rs1217955885; called by muse, varscan2
- IDNK | c.51-1555G>A | Intron (SNP) | VAF 7/54 reads (13%) | catalogued as rs1050941429; called by muse, mutect2, varscan2
- KRT40 | c.688-114C>T | Intron (SNP) | VAF 18/124 reads (15%) | called by muse, mutect2, varscan2
- LYPLA2P2 | n.432del | RNA (DEL) | VAF 28/126 reads (22%) | called by mutect2, pindel*, varscan2
- MBD2 | c.542+1660T>C | Intron (SNP) | VAF 15/83 reads (18%) | called by muse, mutect2, varscan2
- MORF4 | n.432G>A | RNA (SNP) | VAF 17/140 reads (12%) | called by muse, mutect2, varscan2
- NR4A1 | c.160+3570G>A | Intron (SNP) | VAF 25/122 reads (20%) | called by muse, mutect2, varscan2
- RAD51D | c.*626G>A | 3'UTR (SNP) | VAF 53/367 reads (14%) | catalogued as rs1444205582; called by muse, mutect2, varscan2
- RASAL1 | c.1513-288C>A | Intron (SNP) | VAF 28/97 reads (29%) | called by muse, mutect2, varscan2
- STPG1 | c.*77G>A | 3'UTR (SNP) | VAF 50/198 reads (25%) | called by muse, mutect2, varscan2
- TBX2 | chr17:61412026 C>T | 3'Flank (SNP) | VAF 37/215 reads (17%) | catalogued as rs777618141; called by muse, mutect2, varscan2
- VSIG10L | c.*100C>G | 3'UTR (SNP) | VAF 11/97 reads (11%) | called by muse, mutect2, varscan2
